Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3460, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3460-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right renal mass

Source of Specimen(s):

- 1: Peri renal fat
- 2: Rt. Renal Mass

Gross Description:

Part 1

Source of Tissue: Right Perinephric Fat

Gross Description: The specimen is received fresh labeled Right Perinephric Fat and consists of multiple soft yellow tan, irregular fibrofatty tissue fragments, measuring 25 x 18 x 8.5 cm. The specimen is sectioned to show a soft yellow, thin fibrofatty cut surface with no obvious discrete masses present. Representative sections are submitted in 1A through 1C.

Part 2

Source of Tissue: Right Renal Mass Stitch marks deep surface

Gross Description: The specimen is received fresh labeled Right Renal Mass Stitch marks deep surface and consists of a well encapsulated, firm mass measuring 3.3 x 3 x 2 cm. The orientation suture is identified. The deep margin is inked black. The specimen is serially sectioned to reveal a golden yellow, soft cut surface. The lesion comes within less than 0.1 cm of the deep margin. The attached perinephric fat measures 8.5 x 5.5 x 4 cm. The perinephric fat is sectioned to show a homogenous, soft yellow thin fibrofatty cut surface. Representative section of the deep margin with closest tumor is frozen in 2FS. Additional random sections of the specimen are submitted in 2A through 2B.

- 2A, 2B with remainder of deep margin closest to tumor
2C Tumor of closest capsule
2D Perinephric fat

Final Diagnosis:

1. Right perinephric fat:

[page 2 of 2]
- No tumor seen.

2. Right renal mass, excision:

- Renal cell carcinoma, conventional clear cell type, [REDACTED] grade 2, (3.3 cm).

- Resection margin free of tumor.

- Tumor confined to the kidney.

- Non-neoplastic tissue with moderate arteriolonephrosclerosis.

- pT1a Nx Mx

FCGTL: Chromo15, Chrom45, Interp

Procedures/Addenda

FC Cytogenetics Solid

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Right Renal Mass

KARYOTYPE: Abnormal mosaic [REDACTED] karyotype:

56

70<3n>,XX,-Y,-3,+5,+7,-9,+11,+12,-13,-14,-15,+16[cp17]/46,XY[3]

RESULTS: The renal mass was harvested after nine days in culture. The chromosomes from twenty metaphases were counted and analyzed, and four of these metaphases were karyotyped by G-banding. Seventeen cells had between 56 and 70 chromosomes and contained multiple numerical abnormalities described above. Of particular significance were the loss of chromosome 3 and gain of chromosome 5, findings that are consistent with the diagnosis of clear cell renal cell carcinoma. Three cells had a modal number of 46 chromosomes and appeared to have a normal karyotype.

Source: NCI Genomic Data Commons file 00117a5c-d9eb-4081-be23-35eb193949fc (TCGA-AK-3460.95FC84F5-4FB3-4CE7-ACD0-C7E0D8F03DD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).